Somatic mutation profile of tumor specimen TCGA-12-0819-01A (aliquot TCGA-12-0819-01A-01W-0424-08) from TCGA case TCGA-12-0819, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.7 years (18,160 days).
Specimen TCGA-12-0819-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cff3561-ba10-4d18-92d8-5d2b4536782a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0819-10A (Blood Derived Normal), aliquot TCGA-12-0819-10A-01W-0424-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e78edf3e-3748-4417-8c9e-2c8d7764a38d

The open-access MAF lists 52 somatic variants for this specimen: 39 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Splice Site 2, Nonsense Mutation 2, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSP | c.8501G>A p.R2834H | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs121912999, CM063960, COSV60940835; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM18 | c.2057A>G p.N686S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99695392; called by muse, mutect2, varscan2
- ADORA1 | c.677A>T p.Y226F | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.464); catalogued as COSV104370786, COSV99704486; called by muse, mutect2, varscan2
- ANAPC4 | c.1485_1486insA p.Q496Tfs*4 | Frame Shift Ins (INS) | VAF 185/577 reads (32%) | catalogued as COSV100193964; called by mutect2, pindel, varscan2
- CLTC | c.3874-2A>G p.X1292_splice | Splice Site (SNP) | VAF 67/482 reads (14%) | catalogued as COSV99292061; called by muse, mutect2, varscan2
- COL11A1 | c.5243C>T p.P1748L | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV62179675, COSV62188599; called by muse, mutect2, varscan2
- DCAF8L1 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV101491377; called by muse, mutect2, varscan2
- DDIT4 | c.550del p.R184Dfs*25 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs1179161195; called by mutect2, pindel, varscan2
- DDX43 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 124/425 reads (29%) | catalogued as rs199611536, COSV64837264; called by muse, mutect2, varscan2
- DKC1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65777058; called by muse, mutect2, varscan2
- EPB41 | c.352T>G p.F118V | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100548373; called by muse, mutect2, varscan2
- EPB41L3 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 325/906 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as rs558098862, COSV59453540, COSV59456315; called by muse, mutect2, varscan2
- GGTLC2 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 9/122 reads (7%) | catalogued as COSV101312213; called by muse, mutect2, varscan2
- GSN | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 128/394 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs752400851, COSV57997058; called by muse, varscan2
- IL31RA | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs565501186, COSV51680542; called by muse, mutect2, varscan2
- ITGA8 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 146/267 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747010112, COSV65237255; called by muse, mutect2, varscan2
- KIAA2013 | c.1016C>G p.A339G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.604); catalogued as rs770570625, COSV100927122; called by muse, varscan2
- KRT23 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544856938, COSV52928917; called by muse, mutect2, varscan2
- LRP12 | c.698T>A p.L233H | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99407443, COSV99407563; called by muse, mutect2
- MAP2 | c.2534C>T p.T845I | Missense Mutation (SNP) | VAF 242/675 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV99559387; called by mutect2, varscan2
- MET | c.2714G>A p.S905N | Missense Mutation (SNP) | VAF 111/488 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs753091019, COSV100577169; called by muse, mutect2, varscan2
- MUC17 | c.12302G>A p.R4101Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs986544449, COSV100072820, COSV60279719; called by muse, mutect2, varscan2
- OR4K15 | c.338G>A p.R113H (on ENST00000305051; = p.R89H on NM_001005486.1) | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139377821, COSV100520989; called by muse, mutect2
- PCYOX1L | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 126/345 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380639544, COSV99199177; called by muse, mutect2, varscan2
- PTH2R | c.1537A>G p.T513A | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99782350; called by muse, mutect2, varscan2
- RTL3 | c.543G>C p.E181D | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100329712; called by muse, mutect2, varscan2
- RUNX1 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 486/1328 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100296850; called by muse, mutect2, varscan2
- RYR2 | c.6082C>T p.R2028C | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs767787774, COSV100770120, COSV63695525; called by muse, mutect2, varscan2
- SLC6A18 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777600288; called by muse, mutect2
- SLCO6A1 | c.1347G>A p.M449I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.377); catalogued as COSV101134243, COSV65810967; called by muse, mutect2, varscan2
- TAB2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 108/1046 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs748656776, COSV99644738; called by muse, mutect2, varscan2
- TMEM74B | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1448697040, COSV101121969; called by muse, mutect2, varscan2
- UGT1A6 | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 129/346 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201825340, COSV100530162; called by muse, mutect2, varscan2
- USH2A | c.9352A>G p.I3118V | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100233208; called by muse, mutect2, varscan2
- ZNF521 | c.3338C>T p.T1113M | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as rs1464070905, COSV64124624, COSV64126386; called by muse, mutect2, varscan2
- ZSCAN1 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1568606780, COSV56604618, COSV56604894; called by muse, mutect2, varscan2
- ZZEF1 | c.6894G>T p.V2298= | Splice Region (SNP) | VAF 6/60 reads (10%) | catalogued as COSV101067730; called by muse, mutect2
- CANX | c.442_446+2del p.X148_splice | Splice Site (DEL) | VAF 49/168 reads (29%) | called by mutect2, pindel, varscan2
- AL441992.2 | c.366C>T p.D122= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs757193921, COSV100223503; called by muse, mutect2, varscan2
- CDH18 | c.1281C>T p.D427= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs371583912, COSV99931836; called by muse, varscan2
- GNB5 | c.762C>T p.F254= (on ENST00000261837 / NM_016194.4; = p.F212= on NM_006578.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs144268249; called by muse, mutect2, varscan2
- HCN4 | c.813G>T p.L271= | Silent (SNP) | VAF 8/222 reads (4%) | catalogued as COSV56083140; called by muse, mutect2
- HTR2C | c.648T>A p.L216= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99349004; called by muse, mutect2, varscan2
- KIR3DL2 | c.480C>A p.I160= | Silent (SNP) | VAF 135/1744 reads (8%) | called by muse, mutect2
- MC4R | c.396C>T p.S132= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as COSV100235954; called by muse, mutect2
- MTUS2 | c.1740G>A p.L580= | Silent (SNP) | VAF 79/670 reads (12%) | catalogued as COSV101462170, COSV70914228; called by muse, mutect2, varscan2
- MYOM3 | c.1752C>T p.S584= | Silent (SNP) | VAF 41/341 reads (12%) | catalogued as rs765243510, COSV58390302; called by muse, mutect2
- PKHD1 | c.9669A>T p.S3223= | Silent (SNP) | VAF 88/943 reads (9%) | catalogued as COSV100582648; called by muse, mutect2
- TICAM1 | c.1170G>A p.S390= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV99941083; called by muse, varscan2
- BDNF | c.-21-15485G>A | Intron (SNP) | VAF 46/335 reads (14%) | catalogued as rs1328201124, COSV100151397; called by muse, mutect2
- NT5C1B-RDH14 | c.*81G>T | 3'UTR (SNP) | VAF 161/432 reads (37%) | catalogued as COSV101173320; called by muse, mutect2, varscan2
